CGCI case BLGSP-71-29-00536 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/1e5fed46-22c6-41d3-8b1d-2846d3ca4c6b

Demographics
Sex at birth: female.

Biospecimens (1 sample)
- Sample BLGSP-71-29-00536-50A: Sample type: Cell Lines; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Derived Cell Line; Preservation method: Frozen.
